Somatic mutation profile of tumor specimen BA3416D (aliquot aq-BA3416D) from BEATAML1.0 case 2607, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.5 years (19,916 days).
Specimen BA3416D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb954c2b-c659-4f39-a8ad-534ae4cc2b23.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3338D (Solid Tissue Normal), aliquot aq-BA3338D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17fd871a-7f8d-4e52-9cb3-7174e3dd712c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62004381; called by muse, mutect2, varscan2
- TMEM121B | c.1476C>T p.Y492= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as rs1426480035; called by muse, mutect2, varscan2
